Gene-level copy-number profile of tumor specimen MP2PRT-PASPAA-TMP1-A from MP2PRT case MP2PRT-PASPAA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,055 days).
Specimen MP2PRT-PASPAA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a73758e9-5dd9-49aa-9ad2-e238cb3edf42.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASPAA-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/b17a99c6-c20a-42de-bf0c-e501668ef4b0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 114; copy number 2: 539; copy number 3: 473; copy number 4: 39,591; copy number 5: 6,279; copy number 6: 3; copy number 7: 9,777; copy number 8: 1,393; copy number 9: 2; copy number 11: 722.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:35,254,344–35,256,605, 1 gene (within-gene range 0–4): AC090740.1.
- chr11:55,279,949–55,280,289, 1 gene (within-gene range 0–4): AP005597.2.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–8): TRDD1, TRDD2.
- chr16:10,496,272–10,496,374, 1 gene: RNU6-633P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 724 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:35,539,838–35,556,264, 2 genes, copy number 9: AL033519.4, AL033519.3.
- chr21:13,038,160–46,691,226, 722 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 114. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
